Somatic mutation profile of tumor specimen MP2PRT-PASKKT-TMP1-A (aliquot MP2PRT-PASKKT-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASKKT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.1 years (1,852 days).
Specimen MP2PRT-PASKKT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be827462-fe67-4303-b62a-939ac9083fc5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASKKT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASKKT-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f08e287c-d8e6-42d9-a201-407e3522108f

The open-access MAF lists 10 somatic variants for this specimen: 10 protein-altering or splice-affecting.
By variant classification: Missense Mutation 8, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 87/305 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CASK | c.616G>A p.G206S | Missense Mutation (SNP) | VAF 179/270 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59364692; called by muse, mutect2, varscan2
- KCNH5 | c.2017C>T p.R673W | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751953923, COSV59756448; called by muse, mutect2, varscan2
- MAGEB10 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 138/230 reads (60%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV63312555, COSV63312770; called by muse, mutect2, varscan2
- SI | c.3557G>A p.R1186H | Missense Mutation (SNP) | VAF 96/246 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.388); catalogued as rs762898979; called by muse, mutect2, varscan2
- FAM151A | c.1100T>C p.I367T | Missense Mutation (SNP) | VAF 133/285 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- IGHV4-59 | c.345_346insTCGCG p.R116Sfs*? | Frame Shift Ins (INS) | VAF 40/210 reads (19%) | called by pindel, varscan2
- MYBBP1A | c.3303_3323del p.T1102_L1108del | In Frame Del (DEL) | VAF 173/506 reads (34%) | called by pindel, varscan2*
- PLCZ1 | c.769C>A p.Q257K | Missense Mutation (SNP) | VAF 153/393 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TEK | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.038); called by muse, mutect2, varscan2
